Somatic mutation profile of tumor specimen TCGA-CN-A49C-01A (aliquot TCGA-CN-A49C-01A-11D-A24D-08) from TCGA case TCGA-CN-A49C, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: GX; Age at diagnosis: 67.1 years (24,495 days).
Specimen TCGA-CN-A49C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fad2789-2058-4ea1-8538-06f543bdf7dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A49C-10B (Blood Derived Normal), aliquot TCGA-CN-A49C-10B-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5967529f-3523-4521-87cf-7f1180c0163e

The open-access MAF lists 56 somatic variants for this specimen: 39 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 16, Nonsense Mutation 3, Frame Shift Del 3, In Frame Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMDEC1 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as rs200134300; called by muse, mutect2, varscan2
- BRF1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777141032, COSV59268700; called by muse, mutect2, varscan2
- C7orf61 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100190390; called by muse, mutect2, varscan2
- CCDC113 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778072062, COSV99541209; called by muse, mutect2, varscan2
- CDC123 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 41/116 reads (35%) | catalogued as rs887320669, COSV99827206; called by muse, mutect2, varscan2
- CELF5 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99486179; called by muse, mutect2
- DPP10 | c.1660G>C p.D554H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.592); catalogued as COSV100071461; called by muse, mutect2, varscan2
- EIF2S1 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53600556; called by muse, mutect2, varscan2
- EPHA3 | c.869G>T p.C290F | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV60703339; called by muse, mutect2
- F5 | c.5095G>A p.A1699T | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1281908528, COSV100889229; called by muse, mutect2, varscan2
- FCRLA | c.221A>G p.D74G (on ENST00000367959; = p.D51G on NM_032738.4) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99376610; called by muse, mutect2, varscan2
- GIGYF1 | c.2756T>C p.L919P | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99309984; called by muse, mutect2, varscan2
- GMFB | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1452327858, COSV100794597; called by muse, mutect2, varscan2
- GRHPR | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs774233908, COSV58944706; called by muse, mutect2
- HSP90AB1 | c.989G>A p.R330K | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV100807198; called by muse, mutect2, varscan2
- IGSF1 | c.2549G>A p.R850Q | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); catalogued as rs374589007, COSV63837549; called by muse, mutect2, varscan2
- INPPL1 | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1380449984, COSV53355415; called by muse, mutect2, varscan2
- KIAA2026 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs758942286, COSV67357254; called by muse, mutect2, varscan2
- MAGI3 | c.2392C>T p.R798* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100290368; called by muse, mutect2, varscan2
- NKD1 | c.1132G>C p.V378L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99194125; called by muse, mutect2, varscan2
- NLRP12 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs761571455, COSV60746932, COSV60752024; called by muse, mutect2, varscan2
- NOG | c.25G>T p.V9F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV100240656; called by muse, mutect2, varscan2
- OPA1 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100655469; called by muse, mutect2
- PLCL1 | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101407280, COSV70824270; called by muse, mutect2
- PLEKHG7 | c.1917T>G p.Y639* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100468473; called by muse, mutect2, varscan2
- PRSS8 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752698845, COSV99571785; called by muse, mutect2, varscan2
- PTPRM | c.3680G>A p.R1227H | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs753269616, COSV100156385, COSV59855280; called by muse, mutect2, varscan2
- RUFY1 | c.829G>C p.V277L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV100105813, COSV100106434; called by muse, mutect2, varscan2
- SDK2 | c.3775C>T p.R1259C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); catalogued as rs147343958; called by muse, mutect2, varscan2
- SLC39A8 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV100765909; called by muse, mutect2, varscan2
- SPIN2B | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.899); catalogued as COSV99328211; called by muse, mutect2, varscan2
- SPRY3 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs757256938, COSV100249547, COSV57144488; called by muse, mutect2
- STAT3 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555566945, COSV52890482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF6L | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99585463; called by muse, mutect2, varscan2
- ZNF106 | c.4677+1G>A p.X1559_splice | Splice Site (SNP) | VAF 30/102 reads (29%) | catalogued as COSV99783146; called by muse, mutect2, varscan2
- EPX | c.1384del p.V462Wfs*68 | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | called by mutect2, pindel, varscan2
- FLNC | c.3461_3463delinsT p.D1154Vfs*18 | Frame Shift Del (DEL) | VAF 22/47 reads (47%) | called by pindel, varscan2*
- SLC39A9 | c.743_752del p.L248Pfs*19 | Frame Shift Del (DEL) | VAF 65/238 reads (27%) | called by mutect2, pindel, varscan2
- TACC3 | c.2449_2451del p.K817del | In Frame Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel, varscan2
- CACNG8 | c.483C>T p.G161= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99555151; called by muse, mutect2
- COL5A2 | c.1314T>A p.G438= | Silent (SNP) | VAF 47/98 reads (48%) | catalogued as COSV100880783; called by muse, mutect2, varscan2
- CPSF7 | c.804C>T p.P268= (on ENST00000394888 / NM_001136040.4; = p.P311= on NM_024811.4) | Silent (SNP) | VAF 39/58 reads (67%) | catalogued as COSV100467597; called by muse, mutect2, varscan2
- DCBLD2 | c.912G>A p.A304= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs1402235112, COSV58789203; called by muse, mutect2, varscan2
- DOCK2 | c.756C>T p.V252= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV99915223; called by muse, mutect2, varscan2
- DSCC1 | c.1113C>T p.L371= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100558409; called by muse, mutect2, varscan2
- EFL1 | c.2940G>C p.L980= | Silent (SNP) | VAF 72/158 reads (46%) | catalogued as COSV99188543; called by muse, mutect2, varscan2
- ISOC1 | c.177C>T p.G59= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99434717; called by muse, mutect2, varscan2
- OR51I2 | c.156G>A p.E52= | Silent (SNP) | VAF 43/64 reads (67%) | catalogued as COSV58299341; called by muse, mutect2, varscan2
- SPDYC | c.321C>T p.T107= | Silent (SNP) | VAF 42/191 reads (22%) | catalogued as COSV101017309; called by muse, mutect2, varscan2
- TEX13B | c.66C>T p.I22= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs548824099, COSV100258486, COSV57203368; called by muse, mutect2, varscan2
- TUBGCP6 | c.432G>T p.P144= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV50559943, COSV99352666; called by muse, mutect2, varscan2
- ZKSCAN3 | c.897C>T p.G299= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV99357131; called by muse, mutect2
- ZNF280A | c.279G>C p.V93= | Silent (SNP) | VAF 49/154 reads (32%) | catalogued as COSV100131237; called by muse, mutect2, varscan2
- ZNF792 | c.126G>A p.V42= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV101289749; called by muse, mutect2, varscan2
- ZNF804B | c.1632T>C p.D544= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs750946990, COSV60818484; called by muse, mutect2, varscan2
- TPD52L2 | c.477-1613C>T | Intron (SNP) | VAF 18/275 reads (7%) | catalogued as rs761335673, COSV99410871; called by muse, mutect2
